Somatic mutation profile of tumor specimen TCGA-D7-6521-01A (aliquot TCGA-D7-6521-01A-11D-1800-08) from TCGA case TCGA-D7-6521, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; Tumor grade: G3; Age at diagnosis: 65.1 years (23,776 days).
Specimen TCGA-D7-6521-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60a67356-f603-4e28-a9d9-4209048ef168.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6521-10A (Blood Derived Normal), aliquot TCGA-D7-6521-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65fcabf9-23b9-48c5-a44b-ebede3ab5733

The open-access MAF lists 63 somatic variants for this specimen: 54 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 48, Silent 9, Nonsense Mutation 4, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852404, CM930213, COSV64270281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHEX | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as rs1569442206, COSV65074178; ClinVar: likely pathogenic; called by muse, mutect2
- RHOA | c.125A>C p.Y42S | Missense Mutation (SNP) | VAF 19/141 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs552053449, COSV53570956; called by muse, mutect2, varscan2
- AMY2B | c.51T>A p.Y17* | Nonsense Mutation (SNP) | VAF 23/222 reads (10%) | catalogued as COSV100796202; called by muse, mutect2, varscan2
- ANKRD44 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1426907521, COSV56550586, COSV56557381; called by muse, mutect2, varscan2
- APLP1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs778308918, COSV55702037; called by muse, mutect2, varscan2
- ARHGAP20 | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52807516; called by muse, mutect2, varscan2
- ARID1A | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV61373026; called by muse, mutect2, varscan2
- BPIFB3 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs202072797, COSV64956812; called by muse, mutect2, varscan2
- CBX6 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1184992423, COSV53320403; called by muse, mutect2, varscan2
- CCDC40 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV53897513; called by muse, mutect2, varscan2
- CLK3 | c.785G>A p.R262H (on ENST00000395066 / NM_001130028.1; = p.R114H on NM_003992.4) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs773020998, COSV61411858; called by muse, mutect2
- DAOA | c.132T>G p.I44M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61601784; called by muse, varscan2
- DDX28 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1299524601, COSV60105606; called by muse, mutect2, varscan2
- DMD | c.7429C>T p.R2477W | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs759274835, COSV58895660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51778897; called by muse, mutect2
- ENPEP | c.500A>C p.E167A | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1560548272, COSV54447842; called by muse, mutect2, varscan2
- FAM163B | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63203877, COSV63206673; called by muse, mutect2, varscan2
- FAM83G | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58755886; called by muse, mutect2, varscan2
- GALNT5 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV52036227; called by muse, mutect2
- GMDS | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66429925; called by muse, mutect2
- H1-1 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs952509886, COSV55118888, COSV55119017; called by muse, mutect2
- JAG1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV54754217; called by muse, mutect2
- KCNN1 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs868614193, COSV55837393; called by muse, mutect2
- KIF21B | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as rs267598289, COSV59753464; called by muse, mutect2, varscan2
- LDAH | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1187288247, COSV52968838; called by muse, mutect2
- LZTS3 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs866157932, COSV61277179; called by muse, mutect2, varscan2
- MAGEE2 | c.184G>T p.V62F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs142989384, COSV64897429; called by muse, mutect2, varscan2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- NAP1L1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV53873704; called by muse, mutect2
- OAS3 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV57444490; called by muse, mutect2, varscan2
- OR2T12 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs753611689, COSV58776674; called by muse, mutect2, varscan2
- PCDHB7 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs782318542, COSV50756029; called by muse, mutect2
- PDCL2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs190198366; called by muse, mutect2, varscan2
- PDE3B | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.965); catalogued as COSV56380461; called by muse, mutect2, varscan2
- PLXNA4 | c.2785T>C p.F929L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV58109654; called by muse, mutect2, varscan2
- POTEE | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771613157, COSV100387147; called by muse, varscan2
- POTEE | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs1223463336, COSV100387148; called by muse, varscan2
- RHOA | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69041889, COSV69043206; called by muse, mutect2, varscan2
- RP1 | c.3470C>T p.S1157F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV55111961; called by muse, mutect2, varscan2
- RUNX1T1 | c.755G>A p.G252D (on ENST00000265814 / NM_001198628.1; = p.G225D on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1484910819, COSV56139828; called by muse, mutect2, varscan2
- SALL3 | c.191C>A p.A64E | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV73305834, COSV73306026; called by muse, mutect2, varscan2
- SIRT1 | c.2005A>G p.S669G | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.985); catalogued as COSV53017319; called by muse, mutect2, varscan2
- TAF1L | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.359); catalogued as rs779654443, COSV54258649, COSV99644196; called by muse, mutect2, varscan2
- TGM7 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71772611; called by muse, mutect2
- TROAP | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.058); catalogued as rs201922610, COSV57743320; called by muse, mutect2, varscan2
- TRPC4 | c.2618G>A p.R873H (on ENST00000379705 / NM_016179.4; = p.R878H on NM_003306.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.285); catalogued as rs142683062; called by muse, mutect2, varscan2
- WSCD2 | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV54579122; called by muse, mutect2, varscan2
- ZNF479 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV58636537; called by muse, mutect2, varscan2
- ZNF675 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63095209; called by muse, mutect2
- ZSWIM7 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs775419383, COSV67886862; called by mutect2, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | called by mutect2, pindel
- ZNF329 | c.21_23del p.R8del | In Frame Del (DEL) | VAF 44/181 reads (24%) | called by mutect2, pindel, varscan2
- BOC | c.2136C>T p.P712= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs147219655; called by muse, mutect2, varscan2
- DNAH5 | c.2817G>A p.T939= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs1338338371, COSV54208903; called by muse, mutect2, varscan2
- NPAS3 | c.283C>A p.R95= (on ENST00000356141 / NM_001164749.2; = p.R65= on NM_022123.3) | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs369802852, COSV58112523; called by muse, mutect2, varscan2
- PAMR1 | c.387C>A p.G129= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV53510340, COSV53514007; called by muse, mutect2, varscan2
- PCDHB3 | c.1596C>T p.G532= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs782150356, COSV50563873; called by muse, mutect2, varscan2
- PTCH2 | c.3474C>T p.T1158= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV63400202; called by muse, mutect2, varscan2
- RECQL5 | c.1260C>T p.F420= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs192546084; called by muse, mutect2, varscan2
- TRPV6 | c.2297G>A p.*766= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV63890849; called by muse, mutect2
- TRRAP | c.5484G>C p.L1828= (on ENST00000359863 / NM_001244580.1; = p.L1810= on NM_003496.3) | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as rs185196588; called by muse, mutect2
